Gene-level copy-number profile of tumor specimen TCGA-AR-A1AN-01A from TCGA case TCGA-AR-A1AN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.5 years (16,974 days).
Specimen TCGA-AR-A1AN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.cc0c2c46-bf0a-4a5d-b441-55037838b7d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/887e1629-39d4-4f92-a31a-e5bf8156b52b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,428; copy number 2: 38,842; copy number 3: 2,618; copy number 4: 1,550; copy number 5: 502; copy number 6: 688; copy number 7: 182; copy number 9: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AN-01A-11D-A12N-01): tumor purity 0.55, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,374 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:172,210,711–175,743,616, 64 genes, copy number 5 (broad region; genes not listed).
- chr1:212,686,417–223,395,465, 147 genes, copy number 5 (broad region; genes not listed).
- chr3:160,432,445–161,372,880, 16 genes, copy number 5 (within-gene range 2–5): TRIM59, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB.
- chr3:178,272,932–183,463,201, 102 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:46,035,769–46,244,215, 2 genes, copy number 9: GABRG1, AC104072.1.
- chr4:67,558,727–76,421,868, 207 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr4:76,509,284–76,575,626, 4 genes, copy number 7: AC112249.1, RNU6-145P, MIR4450, MIR548AH.
- chr4:84,491,987–85,011,277, 9 genes, copy number 7 (within-gene range 4–7): NKX6-1, RPL3P13, CDS1, WDFY3, RN7SL552P, WDFY3-AS1, RNU6-469P, WDFY3-AS2, AC108021.1.
- chr8:127,794,526–128,187,101, 1 gene, copy number 5 (within-gene range 3–5): PVT1.
- chr8:127,999,131–128,388,636, 8 genes, copy number 5 (within-gene range 3–5): RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1.
- chr13:52,703,264–114,337,626, 688 genes, copy number 6 (broad region; genes not listed).
- chr15:55,340,032–55,408,510, 1 gene, copy number 5 (within-gene range 3–5): CCPG1.
- chr15:55,355,248–56,245,082, 16 genes, copy number 5 (within-gene range 1–5): DNAAF4-CCPG1, MIR628, C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1, AC009997.1, NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1.
- chr20:47,160,838–49,794,914, 60 genes, copy number 5–7: AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1, AL121888.2, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P.
- chr20:57,351,223–57,620,576, 11 genes, copy number 7: RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1.
- chr20:58,309,715–59,460,837, 38 genes, copy number 7: RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1.

Autosomal genes at a single copy (total copy number 1): 15,428. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
